Somatic mutation profile of tumor specimen ALCH-B2TO-TTP1-A (aliquot ALCH-B2TO-TTP1-A-2-0-D-A78Q-36) from ALCHEMIST case ALCH-B2TO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.6 years (26,160 days).
Specimen ALCH-B2TO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92fa0dd3-9414-4d0e-8c76-539dbc285ac8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2TO-NB1-A (Blood Derived Normal), aliquot ALCH-B2TO-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c57cbe04-afbe-4e43-9ffd-5a12590a023b

The open-access MAF lists 535 somatic variants for this specimen: 361 protein-altering or splice-affecting, 107 silent, 67 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 319, Silent 107, Intron 34, Nonsense Mutation 20, RNA 12, 3'UTR 8, Splice Site 8, 5'Flank 7, Splice Region 6, Frame Shift Del 5, 5'UTR 3, 3'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.752del p.G251Vfs*36 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as rs1131690948, COSV100480629; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCC9 | c.3381G>A p.M1127I | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV53962382; called by muse, mutect2, varscan2
- ACTN2 | c.1513G>T p.E505* | Nonsense Mutation (SNP) | VAF 58/212 reads (27%) | catalogued as rs34193420; called by muse, mutect2, varscan2
- ADAMTS10 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs1555739413, CM142271, COSV54352645, COSV99547162; called by muse, mutect2, varscan2
- ADAMTS18 | c.2320G>C p.A774P | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51418497; called by muse, mutect2, varscan2
- ADGRB3 | c.1403C>A p.S468Y | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1167517276; called by muse, mutect2, varscan2
- ATP1A2 | c.371C>A p.S124Y | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV63405050, COSV63405889; called by muse, mutect2, varscan2
- ATPAF2 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 15/155 reads (10%) | catalogued as rs1178309677; called by muse, mutect2, varscan2
- BBOX1 | c.503G>T p.R168M | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54191696; called by muse, mutect2, varscan2
- BEND2 | c.238+1del p.X80_splice | Splice Site (DEL) | VAF 10/88 reads (11%) | catalogued as COSV104430198; called by mutect2, pindel
- BOD1L1 | c.7219G>C p.G2407R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs1198180386; called by mutect2, varscan2
- CAVIN4 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.127); catalogued as rs768357648; called by muse, mutect2, varscan2
- CDKN2A | c.293A>C p.H98P | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.647); catalogued as COSV58683927, COSV58696031; called by muse, mutect2, varscan2
- CDRT15L2 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.025); catalogued as rs1379116127; called by muse, mutect2, varscan2
- CFAP46 | c.7502-1G>A p.X2501_splice | Splice Site (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99585726; called by muse, mutect2
- CLEC14A | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs747234597; called by muse, mutect2, varscan2
- CNTN3 | c.129T>G p.D43E | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV55179778, COSV99724400; called by muse, mutect2, varscan2
- CSMD1 | c.3767C>A p.T1256N (on ENST00000520002; = p.T1255N on NM_033225.6) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs748026525; called by muse, mutect2, varscan2
- CYP24A1 | c.909T>A p.C303* | Nonsense Mutation (SNP) | VAF 21/171 reads (12%) | catalogued as rs1036721674; called by muse, mutect2, varscan2
- DCAF12L1 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64422350; called by muse, mutect2
- DLL1 | c.1969G>T p.A657S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV64538712; called by muse, mutect2, varscan2
- DNAH1 | c.4921G>A p.E1641K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs754476644; called by mutect2, varscan2
- DNAH7 | c.11981C>G p.T3994R | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56764883; called by muse, mutect2
- DNAJC13 | c.2534G>C p.G845A | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs779235373; called by muse, mutect2, varscan2
- DYSF | c.3061G>C p.E1021Q | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs1207540006, COSV50301412; called by muse, mutect2, varscan2
- ELF2 | c.199del p.A67Qfs*45 | Frame Shift Del (DEL) | VAF 12/114 reads (11%) | catalogued as COSV55492783; called by mutect2, pindel
- EPG5 | c.1115C>G p.S372C | Missense Mutation (SNP) | VAF 30/266 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV99957087; called by muse, mutect2, varscan2
- EPX | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.646); catalogued as rs1247379629; called by muse, mutect2, varscan2
- ESCO2 | c.1254C>G p.I418M | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1330059228; called by muse, mutect2, varscan2
- ESF1 | c.219C>A p.D73E | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs748310039; called by muse, mutect2, varscan2
- ESYT1 | c.606G>C p.Q202H | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV57271357; called by muse, mutect2, varscan2
- FAM111B | c.1207C>G p.P403A | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as rs1485419741; called by muse, mutect2, varscan2
- FAT3 | c.2363C>A p.P788H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as rs751042976, COSV53090601; called by muse, mutect2, varscan2
- FAT3 | c.13300C>G p.L4434V | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as COSV53130831; called by muse, varscan2
- FER1L6 | c.4837G>C p.E1613Q | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.643); catalogued as COSV67548906; called by muse, mutect2, varscan2
- FLCN | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.041); catalogued as COSV53260421; called by muse, mutect2, varscan2
- FLG2 | c.1054C>A p.Q352K | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as rs764387954; called by muse, mutect2
- GABRB3 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs769077258, COSV54660540; called by muse, mutect2, varscan2
- GCG | c.208C>A p.R70S | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as rs745902596, COSV64961725; called by muse, mutect2, varscan2
- GLMP | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs766499648, COSV55296323; called by muse, mutect2
- GRM7 | c.1142C>T p.S381L | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.991); catalogued as rs866626290, COSV100737613; called by muse, mutect2, varscan2
- HLA-E | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as rs1342756789; called by muse, mutect2
- HMX1 | c.744G>C p.K248N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101272890; called by muse, mutect2, varscan2
- INPP5D | c.3422C>T p.P1141L (on ENST00000445964 / NM_001017915.3; = p.P1140L on NM_005541.5) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs761717768; called by muse, mutect2, varscan2
- IRAK1 | c.943C>G p.R315G | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs12860727; called by muse, mutect2, varscan2
- IRX4 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs957263605, COSV51472592; called by muse, varscan2
- ITGB2 | c.2118G>C p.M706I (on ENST00000302347; = p.M682I on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs755049310; called by muse, mutect2, varscan2
- JAKMIP3 | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 15/99 reads (15%) | catalogued as COSV53825542; called by muse, mutect2, varscan2
- KDM3A | c.2458C>G p.P820A | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.145); catalogued as COSV57226141; called by muse, mutect2
- KLHDC1 | c.958G>C p.D320H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63778760; called by muse, mutect2, varscan2
- KLHL12 | c.1175G>T p.R392L | Missense Mutation (SNP) | VAF 19/206 reads (9%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.999); catalogued as COSV66127198; called by muse, mutect2, varscan2
- KTN1 | c.2637G>A p.M879I | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs757589325; called by muse, mutect2, varscan2
- LANCL3 | c.821G>T p.C274F | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.178); catalogued as COSV66130054; called by muse, mutect2, varscan2
- MAGEA3 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV64756493; called by muse, mutect2, varscan2
- MAGED2 | c.1234G>T p.V412L | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.138); catalogued as COSV99514703; called by muse, mutect2, varscan2
- MAPK1IP1L | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.21); catalogued as rs763496056; called by muse, mutect2, varscan2
- MPP3 | c.695G>C p.R232P | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68198809; called by muse, mutect2
- MUC16 | c.34793G>A p.R11598K | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.01); catalogued as rs1207181183; called by muse, mutect2, varscan2
- MXRA5 | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs756710667; called by muse, mutect2
- MYRIP | c.241T>G p.C81G | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746972946; called by muse, mutect2, varscan2
- MYT1L | c.417T>A p.D139E | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67730332, COSV99062542; called by muse, varscan2
- NAV3 | c.6859G>T p.E2287* (on ENST00000397909 / NM_001024383.2; = p.E2265* on NM_014903.6) | Nonsense Mutation (SNP) | VAF 13/88 reads (15%) | catalogued as COSV57096780; called by muse, mutect2
- NBPF12 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 20/405 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as rs1483822969; called by muse, mutect2
- NCKIPSD | c.463G>T p.G155W | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV53660659; called by muse, mutect2
- NELL1 | c.829G>C p.G277R | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100125757; called by muse, mutect2, varscan2
- NLRP10 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1337384075, COSV60781578; called by muse, mutect2, varscan2
- NLRX1 | c.1964C>T p.A655V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.254); catalogued as COSV52703532; called by muse, mutect2, varscan2
- NOD2 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.071); catalogued as rs983465914; called by muse, mutect2, varscan2
- NUAK1 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54602125; called by muse, mutect2
- OBSCN | c.13697C>T p.T4566I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as rs1436106304; called by muse, mutect2, varscan2
- OCLN | c.1556G>C p.R519T | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs762310597, COSV62285750; called by muse, mutect2
- ODR4 | c.256G>T p.G86* | Nonsense Mutation (SNP) | VAF 20/70 reads (29%) | catalogued as rs780989697; called by muse, mutect2, varscan2
- OR1M1 | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101447563; called by muse, mutect2, varscan2
- OR2A5 | c.490C>A p.L164M | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.881); catalogued as COSV101278694; called by muse, mutect2, varscan2
- OR2F2 | c.385C>A p.R129S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs375593151; called by muse, mutect2, varscan2
- OR4D11 | c.800C>A p.T267K | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as rs1384765516, COSV57586154; called by muse, mutect2, varscan2
- OR6F1 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as rs370308508, COSV57467470; called by muse, varscan2
- P2RY4 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.889); catalogued as rs746337541; called by muse, mutect2, varscan2
- PCDHB1 | c.1432G>T p.D478Y | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60631440; called by muse, mutect2, varscan2
- PCDHB12 | c.2050G>A p.D684N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.081); catalogued as rs781967954, COSV99507861; called by muse, mutect2, varscan2
- PCDHB15 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.076); catalogued as rs781796054; called by muse, mutect2, varscan2
- PCDHGA3 | c.1235G>T p.R412L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs759071710; called by muse, mutect2, varscan2
- PIEZO2 | c.7859G>T p.R2620I | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV99554909; called by muse, mutect2
- PLEKHN1 | c.1666G>A p.A556T (on ENST00000379409; = p.A504T on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as rs1470808686; called by muse, mutect2, varscan2
- PSMB3 | c.17A>G p.Y6C | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs1489193205; called by muse, mutect2
- RBM10 | c.946A>T p.I316F | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV61310630; called by muse, mutect2, varscan2
- ROPN1L | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776702691; called by muse, mutect2
- RSPO2 | c.263C>A p.P88Q | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV99058984; called by muse, mutect2
- RTL9 | c.2446G>T p.G816* | Nonsense Mutation (SNP) | VAF 21/166 reads (13%) | catalogued as COSV71825505; called by muse, mutect2, varscan2
- RYR2 | c.3055G>T p.G1019C | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100771940; called by muse, mutect2, varscan2
- RYR3 | c.1861G>C p.D621H | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101212191; called by muse, mutect2
- SAG | c.64del p.R22Gfs*5 | Frame Shift Del (DEL) | VAF 15/133 reads (11%) | catalogued as COSV101300707; called by mutect2, pindel, varscan2
- SERPINA12 | c.71G>A p.S24N | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1232490711; called by muse, mutect2, varscan2
- SETBP1 | c.4763G>C p.R1588P | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as rs948065620, COSV99955488; called by muse, mutect2, varscan2
- SLAIN1 | c.1574C>T p.S525L (on ENST00000466548; = p.S262L on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs544749290, COSV57387419, COSV99934893; called by muse, mutect2
- SLC12A3 | c.591G>T p.K197N | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.915); catalogued as rs1329944232, COSV52638536; called by muse, mutect2, varscan2
- SLC35G3 | c.268C>A p.R90S | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as COSV52013099; called by muse, mutect2, varscan2
- SLC49A4 | c.824G>T p.R275I | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV53749942; called by muse, mutect2, varscan2
- SPANXN3 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 6/138 reads (4%) | catalogued as COSV65140338; called by muse, mutect2
- SPATA31D3 | c.2268G>T p.R756S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.737); catalogued as rs1185591118; called by mutect2, varscan2
- SPINK13 | c.13C>G p.P5A | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV68241221; called by muse, mutect2
- STAP1 | c.462G>T p.Q154H | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.188); catalogued as COSV55326080; called by muse, mutect2
- STK11IP | c.719G>C p.R240P | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV55247423; called by muse, mutect2, varscan2
- STK36 | c.836C>G p.P279R | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as COSV55328599; called by muse, mutect2, varscan2
- TMC1 | c.2177C>T p.A726V | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs573874378, COSV52769526; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM15 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV64990403; called by muse, mutect2, varscan2
- TRPM3 | c.1586C>A p.T529K (on ENST00000357533 / NM_001366142.2; = p.T374K on NM_020952.6) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV62585062; called by muse, mutect2, varscan2
- TRPS1 | c.1374G>T p.Q458H (on ENST00000220888 / NM_001330599.2; = p.Q471H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99631954; called by muse, mutect2, varscan2
- TUT4 | c.1279G>T p.D427Y | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57116805; called by muse, mutect2, varscan2
- USH2A | c.13816G>C p.E4606Q | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56450109; called by muse, mutect2, varscan2
- VCAN | c.2216C>A p.S739Y | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV54113856; called by muse, mutect2, varscan2
- ZFHX4 | c.3113G>T p.G1038V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV51454732; called by muse, mutect2
- ZNF14 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV59849514; called by muse, mutect2, varscan2
- ZNF398 | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60065754; called by muse, mutect2, varscan2
- ZNF534 | c.1111G>A p.E371K (on ENST00000332323 / NM_001143939.3; = p.E358K on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV56521213; called by muse, mutect2
- ABCA8 | c.4471G>C p.E1491Q | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ABCC10 | c.1771C>T p.P591S (on ENST00000372530 / NM_001198934.2; = p.P563S on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2
- ACIN1 | c.2770-2A>G p.X924_splice | Splice Site (SNP) | VAF 19/60 reads (32%) | called by muse, mutect2, varscan2
- ADAM33 | c.1696T>A p.C566S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADD1 | c.741G>T p.A247= | Splice Region (SNP) | VAF 7/65 reads (11%) | called by mutect2, varscan2
- ADGB | c.4415G>T p.W1472L | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ADSS1 | c.512A>T p.Y171F | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AFM | c.1102C>A p.P368T | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.666); called by muse, mutect2
- AGTR2 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 26/207 reads (13%) | called by muse, mutect2, varscan2
- AK8 | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AL592490.1 | c.51G>C p.W17C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALS2 | c.2786G>T p.G929V | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ANK2 | c.2542G>A p.E848K | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ANKRD13A | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ANKRD17 | c.7643C>T p.P2548L | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AP3B1 | c.1834A>T p.K612* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- ARMC3 | c.484C>A p.P162T | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ARMC3 | c.1426-1G>T p.X476_splice | Splice Site (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2
- ARR3 | c.1114G>T p.G372C | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ARRB1 | c.601G>C p.A201P | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.35); called by muse, mutect2
- ASXL3 | c.3494G>T p.C1165F | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATOX1 | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 14/126 reads (11%) | called by muse, mutect2, varscan2
- BCOR | c.4168G>T p.G1390C (on ENST00000378444 / NM_001123385.2; = p.G1356C on NM_017745.6) | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, varscan2
- BOK | c.514-2A>G p.X172_splice | Splice Site (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- BRDT | c.1239T>A p.D413E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- BRWD3 | c.29C>A p.A10D | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- C1orf94 | c.1755C>A p.H585Q (on ENST00000488417 / NM_001134734.2; = p.H395Q on NM_032884.5) | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- C3 | c.3896A>G p.Q1299R | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CACNA2D1 | c.2615G>T p.G872V (on ENST00000356253 / NM_001366867.1; = p.G860V on NM_000722.4) | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CAPN10 | c.688G>T p.G230C | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CBLL2 | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC106 | c.354G>T p.E118D | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC171 | c.1199A>T p.Q400L | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.723); called by muse, mutect2
- CCDC186 | c.560G>C p.G187A | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.359); called by muse, mutect2
- CCDC33 | c.371A>T p.Y124F | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CD44 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- CDH17 | c.2015C>A p.T672K | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- CDH5 | c.854C>A p.P285Q | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- CEP295 | c.5008G>C p.E1670Q | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- CHD7 | c.8425G>T p.V2809L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHRNB3 | c.57del p.T20Qfs*35 | Frame Shift Del (DEL) | VAF 5/47 reads (11%) | called by mutect2, pindel*, varscan2
- CLINT1 | c.1561C>G p.Q521E | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- CNTNAP2 | c.457C>G p.P153A | Missense Mutation (SNP) | VAF 35/308 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNTNAP4 | c.877C>A p.H293N | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.139); called by muse, mutect2
- COG1 | c.1159T>A p.W387R | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- COL22A1 | c.3682G>A p.G1228S | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL22A1 | c.1249G>C p.D417H | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COL24A1 | c.1274A>T p.Q425L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- COL4A6 | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- COL6A5 | c.3259G>T p.A1087S | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- COL7A1 | c.7702C>G p.P2568A | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.9); called by muse, varscan2
- CREBBP | c.4125G>A p.M1375I | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- CSMD1 | c.9631G>T p.D3211Y (on ENST00000520002; = p.D3210Y on NM_033225.6) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2
- CST1 | c.170A>T p.K57M | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by mutect2, varscan2
- CYP27A1 | c.1185-6del | Splice Region (DEL) | VAF 18/167 reads (11%) | called by mutect2, pindel, varscan2
- DACH2 | c.109C>G p.R37G | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.366); called by mutect2, varscan2
- DIXDC1 | c.1613A>G p.D538G (on ENST00000440460 / NM_001037954.4; = p.D327G on NM_033425.4) | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DLX5 | c.104C>A p.P35Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH5 | c.12289G>T p.A4097S | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- DND1 | c.270G>A p.M90I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- DSCAML1 | c.1935C>G p.I645M (on ENST00000321322; = p.I585M on NM_020693.4) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- DSP | c.7643G>T p.R2548L | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- DTX3L | c.1231G>C p.E411Q | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- EDC4 | c.2727G>A p.W909* | Nonsense Mutation (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- EEFSEC | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EEFSEC | c.1002G>T p.K334N | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- EFNB2 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- ELMO1 | c.1368C>A p.F456L | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.242); called by muse, mutect2
- ENPP5 | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2
- EPHA3 | c.1173C>A p.N391K | Missense Mutation (SNP) | VAF 30/261 reads (11%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ERCC6L2 | c.3897A>T p.K1299N | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.033); called by muse, mutect2
- ERO1B | c.814G>T p.G272C | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); called by muse, mutect2
- ERO1B | c.813G>T p.W271C | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- FAM135B | c.3804G>T p.M1268I | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FAM227B | c.507A>T p.E169D | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- FANCA | c.3191G>T p.S1064I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- FCRL5 | c.831G>T p.W277C | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- FCRL5 | c.830G>T p.W277L | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.64); PolyPhen benign (0.145); called by muse, mutect2
- FER1L6 | c.1288G>T p.D430Y | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2
- FETUB | c.611C>A p.S204Y | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- FLG | c.4780G>C p.V1594L | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.053); called by muse, mutect2
- FLG | c.3928G>T p.G1310W | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- FNBP1L | c.456G>C p.Q152H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FRMPD3 | c.10C>G p.L4V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated, low confidence (0.08); called by muse, mutect2, varscan2
- FSIP1 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.846); called by muse, varscan2
- GABRA1 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GAS7 | c.1273C>A p.Q425K (on ENST00000432992 / NM_201433.2; = p.Q285K on NM_003644.3) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.012); called by muse, mutect2
- GBGT1 | c.542dup p.M181Ifs*13 | Frame Shift Ins (INS) | VAF 6/48 reads (13%) | called by mutect2, pindel, varscan2
- GFRA2 | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- GLA | c.86C>A p.A29D | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- GOLGA1 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GRM4 | c.2691G>C p.A897= | Splice Region (SNP) | VAF 34/145 reads (23%) | called by muse, mutect2, varscan2
- GTF2IRD1 | c.2139C>G p.F713L (on ENST00000265755 / NM_016328.3; = p.F698L on NM_005685.4) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.06); called by muse, mutect2
- GUCY1A2 | c.1612A>T p.T538S | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- HDAC9 | c.2662C>A p.L888I | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2
- HECTD4 | c.6590G>C p.R2197T | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- HOXA10 | c.1166T>A p.M389K | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HRG | c.1483C>G p.P495A | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.294); called by muse, mutect2
- HS6ST2 | c.957C>A p.H319Q | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.236); called by muse, mutect2
- HTR2A | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGF1R | c.3679G>C p.E1227Q | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- IGKV3-11 | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- IGSF10 | c.2761C>T p.P921S | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- INHBE | c.718T>A p.C240S | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- INMT | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.33); called by muse, mutect2
- IPO11 | c.2704G>C p.E902Q | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ITPR1 | c.97G>T p.V33F | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- KCNJ1 | c.458G>T p.C153F | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCP | c.564C>A p.C188* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- KDM5B | c.2657G>T p.S886I | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- KEAP1 | c.1385G>T p.G462V | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF4A | c.2065C>A p.L689I | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- KIF4B | c.3581A>C p.E1194A | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); called by muse, mutect2
- KMT5B | c.1556A>G p.Q519R | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LAX1 | c.211del p.Y71Tfs*10 | Frame Shift Del (DEL) | VAF 14/137 reads (10%) | called by mutect2, varscan2
- LAX1 | c.928G>C p.E310Q | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- LBHD1 | c.193C>G p.P65A | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated, low confidence (0.48); called by muse, mutect2, varscan2
- LRCH2 | c.2011G>T p.A671S | Missense Mutation (SNP) | VAF 21/256 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRGUK | c.1589T>A p.I530N | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LRRC43 | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- MAGEC2 | c.418A>G p.T140A | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.84); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MAGEL2 | c.2549C>A p.A850E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- MAOB | c.1400C>A p.P467Q | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- MAP7D2 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 27/342 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2
- MAP7D2 | c.943T>A p.S315T | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- MARCHF6 | c.2623G>A p.E875K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- MCEE | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 10/179 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2
- MERTK | c.2875G>A p.G959R | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.026); called by muse, mutect2
- MGAM2 | c.232G>C p.D78H | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.216); called by muse, mutect2
- MGAT5B | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2
- MTRNR2L10 | c.8C>A p.T3K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- MUC16 | c.23533G>T p.G7845C | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- MUC16 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- MUC2 | c.1766C>A p.S589Y | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.14); called by muse, mutect2, varscan2
- MYO3A | c.3716G>T p.S1239I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- MYSM1 | c.676A>T p.T226S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- NBEAL2 | c.5356A>G p.T1786A | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2
- NEUROG2 | c.109G>T p.A37S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- NHEJ1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); called by muse, varscan2
- NLRP8 | c.2701C>A p.L901M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOD2 | c.1224C>A p.F408L | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- NPY5R | c.673G>T p.V225F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NUP205 | c.5915G>C p.G1972A | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- NUTM2B | c.2096T>A p.V699E | Missense Mutation (SNP) | VAF 23/369 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); called by muse, mutect2
- OBI1 | c.1996C>T p.Q666* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- OR10G8 | c.474G>T p.Q158H | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- OR1D5 | c.515G>C p.R172P | Missense Mutation (SNP) | VAF 14/231 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2
- OR2C3 | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR2T10 | c.337T>A p.C113S | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR4Q3 | c.399dup p.A134Cfs*4 | Frame Shift Ins (INS) | VAF 14/62 reads (23%) | called by mutect2, pindel, varscan2
- OR51M1 | c.599C>A p.A200D | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- OR52I2 | c.707T>A p.M236K | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, mutect2
- OR56A5 | c.509G>C p.R170T | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ORC1 | c.2221G>A p.D741N | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OTUB2 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- PAK5 | c.1332C>A p.D444E | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, varscan2
- PCDHA8 | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- PCDHB15 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- PCDHB3 | c.759G>C p.E253D | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB5 | c.153C>A p.D51E | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- PCDHB9 | c.634C>A p.L212I | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGA6 | c.1505C>A p.S502Y | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PCDHGA9 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PCNX4 | c.3462A>T p.E1154D (on ENST00000406854 / NM_001330177.2; = p.E920D on NM_022495.5) | Missense Mutation (SNP) | VAF 35/153 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDCL | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- PDCL | c.766G>T p.G256W | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- PHACTR3 | c.233G>T p.W78L | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHEX | c.1888G>T p.A630S | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PID1 | c.376C>T p.R126* (on ENST00000354069 / NM_001330156.1; = p.R124* on NM_017933.5) | Nonsense Mutation (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2, varscan2
- PIGN | c.374C>G p.S125C | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PITRM1 | c.997C>T p.L333F | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLCB4 | c.1040G>T p.R347I | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PPP1R12A | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- PPP4R3C | c.2279A>T p.K760M | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PRPF8 | c.1564T>G p.F522V | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRPSAP2 | c.690G>T p.M230I | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PSIP1 | c.457-2A>G p.X153_splice | Splice Site (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2
- PSMD11 | c.1126+7A>T | Splice Region (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2, varscan2
- PSMD13 | c.1099G>T p.V367L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.038); called by muse, mutect2
- RAD54B | c.2135C>G p.S712C | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RAE1 | c.1020+3G>A | Splice Region (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- RAI14 | c.2125G>T p.V709L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- RANBP10 | c.506T>G p.I169S | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- RAPH1 | c.1702C>G p.R568G (on ENST00000319170 / NM_213589.3; = p.R620G on NM_203365.4) | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- REPS2 | c.1633C>T p.Q545* | Nonsense Mutation (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- RGL3 | c.1526G>A p.C509Y | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNASEK | c.224A>T p.H75L (on ENST00000548577; = p.H36L on NM_001004333.5) | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RYR1 | c.399T>A p.D133E | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SAAL1 | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- SCARB1 | c.633C>G p.L211= | Splice Region (SNP) | VAF 6/146 reads (4%) | called by muse, mutect2
- SDF2 | c.545C>G p.P182R | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- SERPINA11 | c.419C>A p.S140Y | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- SHROOM4 | c.110T>G p.V37G | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SLC39A13 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.14); called by muse, varscan2
- SLC4A7 | c.2122G>T p.V708F | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SLITRK2 | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMC3 | c.1144G>T p.G382* | Nonsense Mutation (SNP) | VAF 25/250 reads (10%) | called by muse, mutect2
- SMC3 | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.848); called by muse, mutect2
- SMCHD1 | c.2803G>C p.D935H | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2
- SORBS1 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SP140 | c.824G>T p.R275M | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.429); called by muse, varscan2
- SPHKAP | c.3443T>A p.L1148Q | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPINK5 | c.162dup p.D55* | Frame Shift Ins (INS) | VAF 14/123 reads (11%) | called by mutect2, pindel, varscan2
- SPTA1 | c.3883C>T p.L1295F | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SSR1 | c.330G>T p.K110N | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- SYN1 | c.852C>A p.N284K | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- SYTL4 | c.149G>C p.G50A | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF10 | c.215C>G p.A72G | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAS2R41 | c.92T>A p.L31Q | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D2B | c.962C>G p.S321* | Nonsense Mutation (SNP) | VAF 43/220 reads (20%) | called by muse, mutect2, varscan2
- TBK1 | c.812+1G>T p.X271_splice | Splice Site (SNP) | VAF 15/93 reads (16%) | called by muse, varscan2
- TCP11X2 | c.772C>A p.P258T | Missense Mutation (SNP) | VAF 34/450 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.192); called by muse, mutect2
- TEX13A | c.929C>G p.S310C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TEX15 | c.7912C>A p.Q2638K (on ENST00000256246; = p.Q3021K on NM_001350162.2) | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.306); called by mutect2, varscan2
- TGOLN2 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 24/275 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2
- THEGL | c.1112C>A p.P371H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- THSD7A | c.4745C>T p.P1582L | Missense Mutation (SNP) | VAF 80/310 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- TMEFF1 | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); called by muse, mutect2
- TMEM132C | c.1506G>C p.M502I | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMEM196 | c.462A>T p.R154S | Missense Mutation (SNP) | VAF 20/227 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2
- TRIM10 | c.896A>T p.E299V | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, varscan2
- TRPM6 | c.4619A>C p.H1540P | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- TSPYL2 | c.462G>T p.W154C | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.667); called by muse, mutect2
- TUBB8 | c.699G>A p.M233I | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TUBB8B | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- TUBG2 | c.533T>A p.M178K | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0.021); called by muse, mutect2
- U2SURP | c.784G>C p.A262P | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- UACA | c.424+1G>T p.X142_splice | Splice Site (SNP) | VAF 21/238 reads (9%) | called by muse, mutect2
- UBE2S | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- USP9X | c.5671G>T p.D1891Y | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- USP9X | c.6476C>G p.A2159G | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- UTP14A | c.1142C>A p.T381N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, varscan2
- WDR25 | c.1483G>A p.G495S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR25 | c.1484G>T p.G495V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- XIRP2 | c.3560T>A p.I1187N (on ENST00000628543; = p.I1362N on NM_152381.6) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- XPO4 | c.266G>T p.S89I | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- ZMYM5 | c.1630C>T p.Q544* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- ZNF233 | c.1316C>G p.S439C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF264 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ZNF354C | c.428T>A p.L143H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF468 | c.109A>G p.M37V | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, varscan2
- ZNF480 | c.248G>T p.R83M | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); called by muse, varscan2
- ZNF480 | c.249G>T p.R83S | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.19); called by muse, varscan2
- ZNF525 | c.612A>T p.Q204H | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- ZNF676 | c.105G>C p.E35D (on ENST00000650058; = p.E3D on NM_001001411.3) | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); called by muse, mutect2
- ZNF804A | c.3435G>C p.Q1145H | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.014); called by muse, mutect2
- ACACB | c.1638C>T p.F546= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV58130189; called by muse, mutect2, varscan2
- ACACB | c.7371C>A p.S2457= | Silent (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2
- ACSM1 | c.765G>C p.R255= | Silent (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- ACVRL1 | c.1440C>G p.L480= | Silent (SNP) | VAF 24/227 reads (11%) | called by muse, mutect2, varscan2
- ADAM15 | c.2568G>A p.P856= (on ENST00000356955 / NM_207197.3; = p.P807= on NM_003815.5) | Silent (SNP) | VAF 16/117 reads (14%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.723C>T p.L241= | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as COSV52814230; called by muse, mutect2, varscan2
- ATP6V1C2 | c.1077G>A p.V359= (on ENST00000272238 / NM_001039362.2; = p.V313= on NM_144583.4) | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as rs771577716; called by muse, mutect2, varscan2
- ATP8B4 | c.2409G>A p.K803= | Silent (SNP) | VAF 34/243 reads (14%) | catalogued as COSV52718648; called by muse, mutect2, varscan2
- BCHE | c.642T>A p.G214= | Silent (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- CAPN6 | c.1101G>C p.L367= | Silent (SNP) | VAF 27/155 reads (17%) | catalogued as COSV60697674; called by muse, mutect2, varscan2
- CBLN2 | c.621C>A p.L207= | Silent (SNP) | VAF 25/164 reads (15%) | called by muse, mutect2, varscan2
- CCSER1 | c.2445A>T p.S815= | Silent (SNP) | VAF 13/83 reads (16%) | called by muse, mutect2, varscan2
- CDH23 | c.5799G>A p.E1933= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV56465373; called by muse, mutect2, varscan2
- CDX4 | c.315C>G p.P105= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV65171676; called by muse, mutect2, varscan2
- CENPB | c.138G>C p.L46= | Silent (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- CNDP1 | c.1059G>A p.E353= | Silent (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- CSAG3 | c.138G>T p.L46= | Silent (SNP) | VAF 34/392 reads (9%) | called by muse, mutect2
- CWH43 | c.1257G>T p.L419= | Silent (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2, varscan2
- CXCL12 | c.184C>A p.R62= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as rs529221485, COSV59107282; called by muse, mutect2, varscan2
- CYP2C19 | c.1320G>T p.L440= | Silent (SNP) | VAF 31/157 reads (20%) | called by muse, mutect2, varscan2
- DALRD3 | c.666G>A p.V222= (on ENST00000341949 / NM_001009996.3; = p.V55= on NM_018114.5) | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as rs746058911; called by muse, mutect2, varscan2
- DCAF8L2 | c.624C>A p.A208= | Silent (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- DCLK2 | c.234G>C p.R78= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs1484063881; called by muse, mutect2, varscan2
- DEDD2 | c.852G>T p.L284= | Silent (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- DOK5 | c.474G>A p.Q158= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as rs1421029775; called by muse, mutect2
- EGFLAM | c.1089C>T p.T363= | Silent (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- EPB41L1 | c.714C>T p.S238= | Silent (SNP) | VAF 23/138 reads (17%) | catalogued as rs773802695, COSV52445338; called by muse, mutect2, varscan2
- EXO1 | c.1131C>T p.P377= | Silent (SNP) | VAF 59/256 reads (23%) | called by muse, mutect2, varscan2
- FAM20B | c.324G>A p.L108= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV99762653; called by muse, mutect2, varscan2
- FAM83E | c.852G>T p.L284= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs1458692463; called by mutect2, varscan2
- FBH1 | c.669G>T p.V223= (on ENST00000362091 / NM_178150.3; = p.V274= on NM_032807.4) | Silent (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- FLNA | c.120G>A p.P40= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as CD1511623, COSV100774714; called by muse, mutect2
- FSCB | c.837T>A p.A279= | Silent (SNP) | VAF 31/132 reads (23%) | called by muse, varscan2
- FSHB | c.195C>A p.I65= | Silent (SNP) | VAF 22/228 reads (10%) | catalogued as COSV99569551; called by muse, mutect2
- GIPR | c.1170C>T p.V390= | Silent (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- GOLGA8J | c.1119C>A p.V373= | Silent (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- GOLGA8S | c.826C>A p.R276= | Silent (SNP) | VAF 20/216 reads (9%) | called by muse, mutect2, varscan2
- GOSR1 | c.726C>T p.I242= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs1802245; called by muse, mutect2, varscan2
- GPAM | c.1725G>T p.G575= | Silent (SNP) | VAF 16/131 reads (12%) | called by muse, mutect2, varscan2
- GRIK3 | c.2649C>A p.P883= | Silent (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- HABP2 | c.546C>T p.F182= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as COSV63637647; called by muse, mutect2, varscan2
- HEATR1 | c.684G>A p.L228= | Silent (SNP) | VAF 19/162 reads (12%) | catalogued as rs767067853; called by muse, mutect2, varscan2
- HEPH | c.711C>T p.L237= (on ENST00000343002; = p.L291= on NM_138737.5) | Silent (SNP) | VAF 18/158 reads (11%) | called by muse, mutect2, varscan2
- HGF | c.1179T>A p.R393= | Silent (SNP) | VAF 12/117 reads (10%) | called by muse, mutect2, varscan2
- HNRNPCL2 | c.789G>T p.G263= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as COSV60402911; called by muse, mutect2, varscan2
- HYDIN | c.2316C>G p.V772= | Silent (SNP) | VAF 5/25 reads (20%) | called by mutect2, varscan2
- ICAM5 | c.1008G>A p.E336= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs760598879; called by muse, mutect2, varscan2
- IFI16 | c.1044A>C p.T348= | Silent (SNP) | VAF 52/160 reads (33%) | catalogued as COSV55541180; called by muse, mutect2, varscan2
- ITGA8 | c.2160A>T p.V720= | Silent (SNP) | VAF 39/283 reads (14%) | called by muse, mutect2, varscan2
- KCNB1 | c.336G>T p.A112= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as rs772069888; called by muse, mutect2, varscan2
- KCP | c.1716C>T p.N572= (on ENST00000620378; = p.N629= on NM_001366122.1) | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as rs936928412; called by muse, varscan2
- KERA | c.522G>A p.Q174= | Silent (SNP) | VAF 20/183 reads (11%) | catalogued as COSV99899470; called by muse, mutect2, varscan2
- KIAA1210 | c.222G>T p.L74= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as COSV68176823; called by muse, mutect2, varscan2
- LAMA2 | c.4656C>G p.A1552= | Silent (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- LRRC14B | c.1209C>A p.R403= | Silent (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- MAOB | c.1401A>C p.P467= | Silent (SNP) | VAF 14/135 reads (10%) | called by muse, mutect2, varscan2
- MMRN2 | c.327C>T p.V109= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs1002730472; called by muse, mutect2, varscan2
- MS4A14 | c.873C>A p.T291= | Silent (SNP) | VAF 19/76 reads (25%) | called by muse, mutect2
- MSN | c.1284C>T p.I428= | Silent (SNP) | VAF 14/90 reads (16%) | called by muse, mutect2, varscan2
- MYH6 | c.1272C>T p.S424= | Silent (SNP) | VAF 36/179 reads (20%) | called by muse, mutect2, varscan2
- MYPN | c.639C>T p.I213= | Silent (SNP) | VAF 16/78 reads (21%) | called by muse, mutect2, varscan2
- NCAPD3 | c.447G>A p.K149= | Silent (SNP) | VAF 22/146 reads (15%) | called by muse, mutect2, varscan2
- NCBP3 | c.816A>G p.G272= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- NEDD9 | c.1602G>T p.V534= | Silent (SNP) | VAF 43/245 reads (18%) | called by muse, mutect2, varscan2
- NKAIN4 | c.516G>A p.T172= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs749411638; called by muse, mutect2, varscan2
- NLRP10 | c.663G>A p.Q221= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs1346125715; called by muse, mutect2, varscan2
- NUP93 | c.1722G>C p.V574= | Silent (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- OPRK1 | c.981C>T p.P327= | Silent (SNP) | VAF 32/172 reads (19%) | called by muse, mutect2, varscan2
- OR52D1 | c.204T>A p.L68= | Silent (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- OR6F1 | c.261G>C p.G87= | Silent (SNP) | VAF 15/70 reads (21%) | called by muse, varscan2
- PABPC3 | c.1215A>T p.T405= | Silent (SNP) | VAF 28/184 reads (15%) | called by muse, varscan2
- PALLD | c.330T>C p.T110= | Silent (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2
- PCDHGA5 | c.474G>T p.R158= | Silent (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- PCDHGC4 | c.636G>A p.L212= | Silent (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- PCLO | c.9267C>G p.V3089= | Silent (SNP) | VAF 17/118 reads (14%) | called by muse, mutect2, varscan2
- PDE1A | c.177G>T p.A59= | Silent (SNP) | VAF 13/129 reads (10%) | called by muse, mutect2
- PIK3R4 | c.1803A>T p.I601= | Silent (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- PLAAT1 | c.465T>A p.P155= (on ENST00000650797; = p.P50= on NM_020386.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/75 reads (13%) | called by muse, varscan2
- PPP1R18 | c.969G>A p.E323= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs1327509245; called by muse, mutect2, varscan2
- PRPF8 | c.5949C>G p.L1983= | Silent (SNP) | VAF 17/121 reads (14%) | called by muse, mutect2, varscan2
- PRPF8 | c.5748C>G p.L1916= | Silent (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- PTPRZ1 | c.5115A>G p.P1705= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as rs1285238838; called by muse, mutect2, varscan2
- RASGRP2 | c.99G>T p.P33= | Silent (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- RENBP | c.651G>T p.G217= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100128700; called by muse, mutect2, varscan2
- RFPL4AL1 | c.621C>G p.L207= | Silent (SNP) | VAF 49/302 reads (16%) | called by muse, mutect2, varscan2
- RSPH9 | c.729C>G p.L243= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs772102571; called by muse, mutect2, varscan2
- RTL1 | c.1050G>T p.L350= | Silent (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- SCARA5 | c.780C>A p.R260= | Silent (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- SECISBP2L | c.561A>G p.K187= | Silent (SNP) | VAF 30/261 reads (11%) | called by muse, mutect2, varscan2
- SELP | c.1725C>G p.L575= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV55248920; called by muse, mutect2, varscan2
- SEMA6D | c.39G>A p.L13= | Silent (SNP) | VAF 19/177 reads (11%) | catalogued as rs1176594653; called by muse, mutect2, varscan2
- SLC2A14 | c.1416C>T p.F472= | Silent (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2, varscan2
- SLC52A3 | c.891G>A p.P297= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs373350870; called by muse, mutect2, varscan2
- SULF2 | c.528G>A p.R176= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs1472848353, COSV63414199; called by muse, mutect2, varscan2
- SV2B | c.864C>G p.T288= | Silent (SNP) | VAF 13/137 reads (9%) | catalogued as COSV100370865, COSV57701658; called by muse, mutect2
- SVEP1 | c.741C>T p.H247= | Silent (SNP) | VAF 24/145 reads (17%) | catalogued as rs757712555; called by muse, mutect2, varscan2
- THBS1 | c.3177G>T p.S1059= | Silent (SNP) | VAF 20/169 reads (12%) | called by muse, mutect2, varscan2
- TMC3 | c.1470C>A p.L490= | Silent (SNP) | VAF 22/119 reads (18%) | called by muse, mutect2, varscan2
- TMEM94 | c.2337C>T p.F779= | Silent (SNP) | VAF 11/81 reads (14%) | catalogued as rs1421093474; called by muse, mutect2, varscan2
- TMTC1 | c.1662G>C p.L554= (on ENST00000539277 / NM_001193451.2; = p.L446= on NM_175861.3) | Silent (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- TRBV4-2 | c.42G>T p.L14= | Silent (SNP) | VAF 24/218 reads (11%) | called by muse, mutect2, varscan2
- TSHZ3 | c.3111G>T p.L1037= | Silent (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- UBE2O | c.1305G>T p.T435= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV60065377; called by muse, mutect2, varscan2
- VASH1 | c.801G>A p.P267= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs372349793; called by muse, mutect2, varscan2
- ZFP62 | c.2274G>T p.V758= (on ENST00000502412 / NM_001377944.1; = p.V725= on NM_152283.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.144G>A p.K48= | Silent (SNP) | VAF 28/294 reads (10%) | catalogued as COSV61333689; called by muse, mutect2
- ZP4 | c.375G>T p.L125= | Silent (SNP) | VAF 16/158 reads (10%) | catalogued as COSV63912043, COSV63913520; called by muse, mutect2
- ABCA4 | c.2918+1039C>A | Intron (SNP) | VAF 21/134 reads (16%) | called by muse, mutect2, varscan2
- AC098650.1 | c.*115+16066C>T | Intron (SNP) | VAF 13/105 reads (12%) | catalogued as rs1421588584; called by muse, mutect2, varscan2
- ADA | c.976-17C>A | Intron (SNP) | VAF 20/171 reads (12%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.1983-439G>A | Intron (SNP) | VAF 7/25 reads (28%) | catalogued as rs766765545; called by muse, mutect2, varscan2
- AMPH | c.1183-1266G>T | Intron (SNP) | VAF 36/125 reads (29%) | called by muse, mutect2, varscan2
- ANKRD10 | c.455+5338G>T | Intron (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2, varscan2
- ANXA13 | c.15+1543G>C | Intron (SNP) | VAF 19/58 reads (33%) | catalogued as rs202199207; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501546 del AG | 5'Flank (DEL) | VAF 10/77 reads (13%) | catalogued as rs1465664101; called by pindel, varscan2
- AP000769.3 | chr11:65503399 del AG | 5'Flank (DEL) | VAF 20/105 reads (19%) | catalogued as rs757173441; called by pindel, varscan2
- AP000769.3 | chr11:65503426 C>T | 5'Flank (SNP) | VAF 12/74 reads (16%) | catalogued as rs901418118; called by muse, varscan2
- C16orf97 | n.28C>A | RNA (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- C4BPB | c.410-1204A>T | Intron (SNP) | VAF 26/329 reads (8%) | called by muse, mutect2
- C5orf64 | n.512+52010C>A | Intron (SNP) | VAF 20/268 reads (7%) | called by muse, mutect2
- C8orf87 | n.161C>T | RNA (SNP) | VAF 12/168 reads (7%) | catalogued as rs1056072776; called by muse, mutect2
- CBLB | c.*33A>C | 3'UTR (SNP) | VAF 3/51 reads (6%) | called by muse, mutect2
- CEP41 | c.*1778C>T | 3'UTR (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- CHIA | c.-137_-135dup | 5'UTR (INS) | VAF 8/64 reads (13%) | called by mutect2, varscan2
- CLEC5A | c.452+19G>T | Intron (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- CLUHP11 | n.783C>G | RNA (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- CNTN4 | c.56-268G>C | Intron (SNP) | VAF 22/184 reads (12%) | called by muse, mutect2, varscan2
- COA8 | c.123+150G>A | Intron (SNP) | VAF 7/82 reads (9%) | called by muse, mutect2
- COL6A3 | c.7669-41C>A | Intron (SNP) | VAF 8/101 reads (8%) | called by muse, mutect2
- EYS | c.1767-8508C>A | Intron (SNP) | VAF 37/223 reads (17%) | called by muse, mutect2, varscan2
- FABP5P3 | chr7:152445590 T>C | 3'Flank (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- FAM193B | c.1275+363C>T | Intron (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2, varscan2
- FAP | c.414-1733G>C | Intron (SNP) | VAF 16/100 reads (16%) | called by muse, mutect2, varscan2
- HACD1 | c.257+1223G>A | Intron (SNP) | VAF 4/36 reads (11%) | catalogued as rs1256463701; called by muse, mutect2, varscan2
- KIAA0895 | c.867+38G>T | Intron (SNP) | VAF 30/86 reads (35%) | called by mutect2, varscan2
- KIAA0895 | c.179-9128C>T | Intron (SNP) | VAF 37/121 reads (31%) | catalogued as rs1427358189; called by muse, mutect2, varscan2
- KLHL14 | c.1069+7698C>A | Intron (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2, varscan2
- LINC00692 | n.516G>T | RNA (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2, varscan2
- MAGEA4 | c.-8G>C | 5'UTR (SNP) | VAF 6/43 reads (14%) | catalogued as COSV99367370; called by muse, mutect2, varscan2
- MEG3 | n.1040-1390C>T | Intron (SNP) | VAF 22/114 reads (19%) | catalogued as rs779205350; called by muse, varscan2
- MIR363 | chrX:134170032 G>T | 5'Flank (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- MIR496 | n.57G>T | RNA (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- MIR892A | n.26A>T | RNA (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- MRAP | c.206+43C>G | Intron (SNP) | VAF 17/128 reads (13%) | called by muse, mutect2, varscan2
- MRRFP1 | n.562G>T | RNA (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2, varscan2
- NELL1 | c.1549+55086G>T | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- NFKBIA | c.*51G>A | 3'UTR (SNP) | VAF 44/214 reads (21%) | called by mutect2, varscan2
- NOC2LP2 | n.811C>A | RNA (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- NPHP4 | c.3644+39G>T | Intron (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- NSG2 | c.*124G>T | 3'UTR (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2
- NSG2 | c.*125G>T | 3'UTR (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- OR4N3P | n.361G>C | RNA (SNP) | VAF 16/314 reads (5%) | called by muse, mutect2
- OR51F5P | n.322G>A | RNA (SNP) | VAF 15/105 reads (14%) | catalogued as rs1167417107; called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157568 C>A | 3'Flank (SNP) | VAF 11/95 reads (12%) | called by muse, mutect2, varscan2
- PSMG3-AS1 | n.3920G>A | RNA (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2, varscan2
- RAB41 | c.*10C>G | 3'UTR (SNP) | VAF 22/166 reads (13%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159145 C>A | 5'Flank (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- RNU6-713P | chr12:40557155 C>A | 5'Flank (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2
- RPL10A | c.5+32C>T | Intron (SNP) | VAF 20/86 reads (23%) | catalogued as rs1165921008; called by muse, mutect2, varscan2
- SERPINA6 | c.613+16C>T | Intron (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- SHB | c.838+589A>G | Intron (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- SLC41A1 | c.*4G>T | 3'UTR (SNP) | VAF 59/181 reads (33%) | called by muse, mutect2, varscan2
- SLC6A10P | n.3214G>T | RNA (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- SMTN | c.1632+634G>T | Intron (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
- SNRNP200 | c.4393-22C>A | Intron (SNP) | VAF 12/83 reads (14%) | called by muse, varscan2
- SYTL5 | c.1155+640G>T | Intron (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
- THNSL2 | c.1229+201G>T | Intron (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100147313; called by mutect2, varscan2
- VSX1 | chr20:25071356 T>A | 3'Flank (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- WT1 | chr11:32438565 C>A | 5'Flank (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2, varscan2
- XG | c.409+20G>T | Intron (SNP) | VAF 18/122 reads (15%) | called by muse, mutect2, varscan2
- XRCC3 | c.*4G>T | 3'UTR (SNP) | VAF 8/54 reads (15%) | called by muse, mutect2, varscan2
- ZNF107 | c.-7A>G | 5'UTR (SNP) | VAF 22/116 reads (19%) | catalogued as COSV61327323; called by muse, varscan2
- ZNF493 | c.-132+8514G>T | Intron (SNP) | VAF 44/133 reads (33%) | catalogued as COSV100371966; called by muse, mutect2, varscan2
- ZNF76 | c.1608+42G>A | Intron (SNP) | VAF 14/143 reads (10%) | called by muse, mutect2, varscan2
